Gene-level copy-number profile of tumor specimen BLGSP-71-32-00699-01A from CGCI case BLGSP-71-32-00699, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 27.2 years (9,947 days).
Specimen BLGSP-71-32-00699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6cda4fbf-40a7-41ce-9fb5-75d1bcf4bd30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-32-00699-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,284 have no estimate.
https://portal.gdc.cancer.gov/files/91e2e91e-c894-47ed-bcb4-f44a8c9e9151

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 790; copy number 2: 56,805; copy number 3: 688; copy number 4: 39; copy number 5: 1; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–2): IGKV2D-14.
- chr7:142,796,697–142,797,502, 6 genes (within-gene range 0–2): TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7.
- chr9:89,449,558–89,450,754, 1 gene (within-gene range 0–1): PA2G4P6.
- chr12:116,801,023–116,801,477, 1 gene (within-gene range 0–2): AC083806.3.
- chr18:76,974,690–76,984,162, 1 gene (within-gene range 0–2): AC093330.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,560,202–150,629,612, 5 genes, copy number 6 (within-gene range 2–6): ADAMTSL4-AS1, RN7SL600P, AL356356.1, ENSA, U4.
- chr20:34,872,146–34,927,962, 1 gene, copy number 5 (within-gene range 2–5): ACSS2.

Autosomal genes at a single copy (total copy number 1): 790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
